FM case AD12392 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Anus and anal canal.
https://portal.gdc.cancer.gov/cases/bd98d63d-ee47-476b-a8c2-d294d0cfaf59

Female, 35.7 years: Melanoma, NOS (ICD-O-3 8720/3) of the anus; metastasis biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
